CGCI case BLGSP-71-30-00650 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e505fd1d-9bc4-48e1-a750-b09281c19fa0

Demographics
Sex at birth: male; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 56.4 years (20,611 days); Year of diagnosis: 2008; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 4,500 days (12.3 years); Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Thyroid; Sites of involvement: Thyroid / Spleen.
   Pathology details: Bone marrow malignant cells: No; Consistent pathology review: No; Lymph node involved site: Axillary; Lymph nodes positive: 1; Lymph nodes tested: 2; Tumor largest dimension diameter: 4.9 cm.
   Pathology details: Lymph node involved site: Cervical, NOS.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CODOX-M; Days to treatment start: 21 days; Days to treatment end: 31 days; Number of cycles: 4; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-IVAC; Days to treatment start: 21 days; Days to treatment end: 31 days; Number of cycles: 4; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Cytarabine + Doxorubicin + Etoposide + Ifosfamide + Methotrexate + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 21 days; Days to treatment end: 31 days; Number of cycles: 4; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Stable Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (5 entries)
- Days to follow up: 0 days; ECOG performance status: 1.
- Days to follow up: 4,094 days (11.2 years); Disease response: Tumor Free.
- Days to follow up: 4,392 days (12.0 years); Disease response: Tumor Free.
- Days to follow up: 4,500 days (12.3 years); Disease response: Tumor Free.
- Follow-up contacts recording only the day: day -549, day 1,607.

Molecular and laboratory tests
- BCL2 (FISH): Normal.
- BCL2 (IHC): Positive.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MIB1 (IHC): Positive.
- MYC translocation (FISH): Abnormal, NOS.
- Lactate Dehydrogenase 436 [Blood test normal range upper: 210].
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Day -549: Comorbidities: HIV/AIDS.
- Day -549: Risk factors: HIV/AIDS.
- Day 0: Cdc hiv risk factors: Homosexual Contact.
- Day 0: Weight: 78 kg; Height: 190 cm; BMI: 21.6; CD4 count: 700; Haart treatment indicator: Yes; HIV viral load: 1407.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-30-00650-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
- Sample BLGSP-71-30-00650-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Biospecimen anatomic site: Lymph Node.
- Sample BLGSP-71-30-00650-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-30-00650-01-BCL6: Tissue microarray coordinates: I3,J3.
  Slide BLGSP-71-30-00650-01-CD20: Tissue microarray coordinates: I3,J3.
  Slide BLGSP-71-30-00650-01-EBER: Tissue microarray coordinates: I3,J3.
  Slide BLGSP-71-30-00650-01-CD3: Tissue microarray coordinates: I3,J3.
  Slide BLGSP-71-30-00650-01-CD10: Tissue microarray coordinates: I3,J3.
  Slide BLGSP-71-30-00650-01-BCL2: Tissue microarray coordinates: I3,J3.
  Slide BLGSP-71-30-00650-01-Ki67: Tissue microarray coordinates: I3,J3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: Haart therapy prior to diagnosis: No; Haart therapy at diagnosis: Yes; Cdc HIV risk group: Homosexual or bisexual contact.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 2; Extranodal involvment other: spleen; Lymph nodes examined: Yes; Other pos node location: neck/thyroid.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 436; Immunophenotypic analysis method: Immunohistochemistry; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: MIB-1.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 3: Genetic abnormality tested: BCL2.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: CODOXMR/IVACR (Magrath protocol); Pharma adjuvant cycles count: 4.

Additional fields from the CGCI biospecimen supplement workbook CGCI-BLGSP_biospecimenSupplementSpreadsheet_TWIST_20220304.xlsx (sheet Sheet1), for sample BLGSP-71-30-00650-01A-01E-0001-01:
- % tumour: 50
